Gene-level copy-number profile of tumor specimen CUPP-B52N-TTM1-A from CCG case CUPP-B52N, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, metastatic, NOS; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 74.6 years (27,240 days).
Specimen CUPP-B52N-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5a457199-38b7-4f08-a3b7-72c3f1d18ab6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B52N-NT1-A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,732 have no estimate.
https://portal.gdc.cancer.gov/files/61dc44e6-31cb-4428-a003-93bd7e3ba5b3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 269; copy number 2: 6,660; copy number 3: 2,668; copy number 4: 38,936; copy number 5: 1,744; copy number 6: 8,372; copy number 7: 216; copy number 8: 18; copy number 9: 3; copy number 10: 4.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:27,872,543–27,886,685, 1 gene: THEMIS2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:242,057,085–242,062,595, 2 genes, copy number 9: TUBB8P6, BX571673.1.
- chr19:9,019,344–9,019,984, 1 gene, copy number 9: BOLA3P2.
- chr20:51,782,331–51,905,030, 4 genes, copy number 10: SALL4, LINC01429, RNU6-347P, RNU7-6P.

Autosomal genes at a single copy (total copy number 1): 232. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
